Somatic mutation profile of tumor specimen TARGET-40-0A4I6O-01A (aliquot TARGET-40-0A4I6O-01A-01D) from TARGET case TARGET-40-0A4I6O, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.4 years (6,738 days).
Specimen TARGET-40-0A4I6O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e0e1890-d91e-4b3c-8abe-5bf972ea4a29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I6O-10A (Blood Derived Normal), aliquot TARGET-40-0A4I6O-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edeeb8fa-6347-4f3e-9de2-baddaf374a30

The open-access MAF lists 28 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 10, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.061); catalogued as CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; called by muse, mutect2, varscan2
- ACTRT2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as rs753334145; called by muse, mutect2, varscan2
- AIRE | c.1300T>G p.C434G | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs1002839491; called by muse, mutect2, varscan2
- C11orf87 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.776); catalogued as rs201132519, COSV100535748; called by muse, mutect2, varscan2
- CD63 | c.323G>C p.R108T | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV57676015; called by muse, mutect2, varscan2
- COL27A1 | c.5407C>T p.R1803W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs145268367; called by mutect2, varscan2
- COL4A3 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67416146; called by muse, mutect2
- INVS | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs368173855; called by muse, mutect2, varscan2
- P3H1 | c.1354dup p.L452Pfs*4 | Frame Shift Ins (INS) | VAF 17/61 reads (28%) | catalogued as rs1323878746; called by mutect2, pindel, varscan2
- ALMS1 | c.9987C>A p.N3329K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- APOB | c.1408C>G p.L470V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CLUH | c.1300G>C p.D434H (on ENST00000435359; = p.D472H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.31852T>G p.F10618V | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.024); called by muse, mutect2
- PRG2 | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- RNF157 | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); called by muse, mutect2
- XPO5 | c.2180G>A p.S727N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- DNAH11 | c.9672C>T p.V3224= | Silent (SNP) | VAF 31/251 reads (12%) | called by muse, mutect2, varscan2
- DNAJC6 | c.1986C>G p.S662= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- KHNYN | c.2022C>T p.L674= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- NWD1 | c.4422T>C p.H1474= | Silent (SNP) | VAF 26/47 reads (55%) | called by muse, mutect2, varscan2
- OTOF | c.1857C>A p.A619= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- PATJ | c.2490T>C p.F830= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1278C>T p.T426= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as rs1460884024, COSV65335785; called by muse, mutect2, varscan2
- RLF | c.129G>T p.A43= | Silent (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- SLC25A44 | c.714C>T p.I238= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- WDR24 | c.369A>G p.E123= (on ENST00000248142; = p.E61= on NM_032259.4) | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- AL353572.2 | n.581A>G | RNA (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- COX20 | c.157+62C>G | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
